Surgical pathology report (de-identified scan), TCGA case TCGA-DB-5278, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-5278-01A (Primary Tumor).

[page 1 of 2]
Final Diagnosis:

Brain, left frontal lobe, excision: Grade 2 (of 4) oligodendroglioma (WHO grade II of III).

TCGA-DB-5278

Immunohistochemical stains for MIB-1 was performed on a paraffin-embedded sections of the brain lesion. The MIB-1 labeling index is low, supporting the above diagnosis.

Results of FISH for 1p19q will be reported in an addendum.

ADDENDA:

1p and 19q FISH studies were performed on cells within paraffin sections from tumor. Two hybridizations were performed: one with a 19q probe/control 19p pair and one with a 1p probe/control 1q pair. The 19q and 1p probes mapped to the regions that are commonly deleted in gliomas. The 19q to 19p probe ratio was 0.60. The 1p to 1q probe ratio was 0.57. For both probes, the normal ratio is approximately 1. Any ratio less than 0.80 is consistent with deletion of the chromosomal region of interest.

The results are abnormal and consistent with deletion of 1p and 19q. Similar results have been observed in glioma specimens, especially oligodendrogliomas.

[page 2 of 2]
be used as an adjunct to existing clinical and pathological information. This test does not rule out other chromosome anomalies.

Preliminary Frozen Section Consultation:

Brain, left frontal lobe, excision: Glioma. Hold over for subclassification and grading.

Gross Description:

Tissue from left frontal brain (2.5 x 2.0 x 1.5 cm).

Block Summary:

Part A: LEFT FRONTAL LESION

- 1 Lt frontal brain
- 2 Lt frontal brain
- 3 Lt frontal brain
- 4 Lt frontal brain
- 5 Lt frontal brain
- 6 Lt frontal brain

END OF REPORT

Page 2 of 2

Source: NCI Genomic Data Commons file cfe8bea8-8c4a-49a2-b74d-10399b5cdb6f (TCGA-DB-5278.B9380181-EB0C-458B-B0C4-38CDF7E06EDC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).